Gene-level copy-number profile of tumor specimen TCGA-IG-A3YB-01A from TCGA case TCGA-IG-A3YB, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 61.1 years (22,316 days).
Specimen TCGA-IG-A3YB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.bcc7ca0e-e3fc-4fb9-ad05-e5905303ae97.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IG-A3YB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2fddf8aa-ff8c-4fb0-b547-fb2389d35310

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 1,316; copy number 2: 18,819; copy number 3: 26,206; copy number 4: 8,968; copy number 5: 2,370; copy number 6: 1,365; copy number 7: 554; copy number 8: 89; copy number 9: 87; copy number 10: 6; copy number 11: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IG-A3YB-01A-11D-A246-01): tumor purity 0.58, ploidy 3.02, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,861,720–38,975,454, 6 genes: AC018693.1, MORN2, RNU6-851P, ARHGEF33, RN7SL96P, AC019171.1.
- chr2:38,992,279–38,993,857, 1 gene: SOS1-IT1.
- chr2:140,586,626–140,586,685, 1 gene: MIR7157.
- chr5:59,528,861–59,529,251, 1 gene: NDUFB4P2.
- chr7:111,091,006–111,125,454, 1 gene: LRRN3.
- chr9:21,929,457–22,128,103, 9 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr12:10,894,943–10,934,845, 3 genes: AC006518.2, TAS2R13, PRH2.
- chr12:10,964,425–11,022,620, 4 genes: TAS2R15P, TAS2R50, TAS2R20, TAS2R19.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 742 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:207,959,292–208,975,307, 10 genes, copy number 7: LINC02767, PLXNA2, AL590138.1, AL606753.1, AL606753.2, LINC01735, LINC02769, RPS26P13, LINC01717, LINC01774.
- chr1:212,285,410–212,361,853, 1 gene, copy number 7 (within-gene range 3–7): PPP2R5A.
- chr1:212,299,495–213,429,077, 30 genes, copy number 7 (within-gene range 3–7): AL360091.3, SNORA16B, AL360091.1, PACC1, AC092803.3, NENF, LINC02771, AC092803.2, LINC01740, AC092803.1, AC092803.4, ATF3, AL590648.2, FAM71A, AL590648.1, LINC02773, BATF3, NSL1, TATDN3, AC104333.3, SPATA45, FLVCR1-DT, AC104333.1, AC104333.2, FLVCR1, AC104333.4, VASH2, ANGEL2, RPS6KC1, RPL31P13.
- chr2:163,743,913–164,843,679, 8 genes, copy number 7 (within-gene range 3–7): AC016766.1, PRPS1P1, CYP2C56P, GRB14, AC107075.1, COBLL1, AC019181.1, SNORA70F.
- chr2:177,953,111–190,203,484, 151 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr2:197,640,441–201,229,406, 67 genes, copy number 8 (broad region; genes not listed).
- chr4:40,743,627–44,025,516, 53 genes, copy number 7: AC131953.2, NSUN7, ARL4AP2, APBB2, AC131953.1, Y_RNA, RNA5SP160, RNU6-836P, RNU6-1195P, UCHL1-AS1, UCHL1, Y_RNA, LIMCH1, RPL12P20, AC108050.1, AC105389.2, OR5M14P, PHOX2B, PHOX2B-AS1, AC105389.1, RNU1-49P, HMGB1P28, LINC00682, AC108210.1, AC108210.2, TMEM33, DCAF4L1, AC106052.1, SLC30A9, ATP1B1P1, BEND4, AC111006.1, AC024022.1, SHISA3, ATP8A1, RPS7P7, CCNL2P1, AC096734.2, AC096734.1, RN7SKP82, GRXCR1, AC111198.1, AC097451.1, AC098590.2, AC098590.1, LINC02383, AC114774.1, RN7SL691P, AC080132.1, RN7SL193P, NDUFB4P12, AC114757.1, LINC02475.
- chr7:6,445,953–21,945,903, 191 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr7:134,127,299–134,264,591, 1 gene, copy number 9 (within-gene range 3–9): LRGUK.
- chr7:144,048,948–144,119,360, 6 genes, copy number 11: OR2A5, OR2A25, OR2A41P, OR2A12, OR2A2, OR2A15P.
- chr7:150,512,559–150,614,764, 6 genes, copy number 10: STRADBP1, GIMAP7, ALDH7A1P3, GIMAP4, AC069304.3, AC069304.1.
- chr7:150,791,285–151,227,205, 22 genes, copy number 8: TMEM176B, TMEM176A, AOC1, KCNH2, NOS3, ATG9B, ABCB8, AC010973.1, ASIC3, CDK5, SLC4A2, AC010973.3, AC010973.2, FASTK, TMUB1, AGAP3, GBX1, ASB10, IQCA1L, H2BE1, ABCF2-H2BE1, ABCF2.
- chr8:76,162,119–77,537,290, 15 genes, copy number 7 (within-gene range 4–7): AC011029.1, RNU2-54P, AC067773.1, LINC01109, LINC01111, ZFHX4-AS1, AC013509.1, MRPL9P1, ZFHX4, AC011716.1, AC023200.1, MIR3149, PEX2, HIGD1AP18, AC062004.1.
- chr12:14,169,746–20,753,386, 95 genes, copy number 7 (broad region; genes not listed).
- chr13:28,820,348–34,083,310, 86 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,316. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
